Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A236, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A236-01A (Primary Tumor).

[page 1 of 4]
ICPAA Discrepancy		☒

Print this Page

Specimen Description

ICD-O-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9 w 4/8/11

Surgical Pathology Report

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med. Rec #: [REDACTED]

Submitting Physician: [REDACTED]

*****Clinical History*****

Papillary carcinoma of thyroid.

*****Final Pathologic Diagnosis*****

- A. Adipose tissue, excision:
- Mature adipose tissue; no parathyroid tissue seen.
- B. Thyroid, total thyroidectomy:
- Papillary thyroid carcinoma with secondary cystic changes, left lobe (see synoptic report).
- Microscopic focus of papillary carcinoma, 2 mm. in greatest diameter, right lobe.
- Small parathyroid gland.
- Small perithyroidal lymph nodes (4/4) involved with microscopic subcapsular foci of metastatic papillary carcinoma.
- C. Parathyroid, excision:
- Lymph node (1/1) with cystic metastasis of papillary carcinoma.

Electronically Signed By
[REDACTED]
[REDACTED]

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:
Specimen type: Total thyroidectomy.
Tumor location: Left lobe.
Tumor size: 3.5 x 3.0 x 2.5 cm.
Histologic type: Papillary carcinoma.
Tumor grade: Low-grade.
Lymphatic/vascular invasion: No.
Capsular invasion: No.
Tumor extent:
Confined to the thyroid: Yes.

[page 2 of 4]
Sex:M

Specimen Description

Surgical Pathology Report

****Clinical History****

Papillary carcinoma of thyroid.

****Final Pathologic Diagnosis****

- A. Adipose tissue, excision:
- Mature adipose tissue; no parathyroid tissue seen.
- B. Thyroid, total thyroidectomy:
- Papillary thyroid carcinoma with secondary cystic changes, left lobe (see synoptic report).
- Microscopic focus of papillary carcinoma, 2 mm. in greatest diameter, right lobe.
- Small parathyroid gland.
- Small perithyroidal lymph nodes (4/4) involved with microscopic subcapsular foci of metastatic papillary carcinoma.
- C. Parathyroid, excision:
- Lymph node (1/1) with cystic metastasis of papillary carcinoma.

Electronically Signed By

****Synoptic Report****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: Total thyroidectomy.

Tumor location: Left lobe.

Tumor size: 3.5 x 3.0 x 2.5 cm.

Histologic type: Papillary carcinoma.

Tumor grade: Low-grade.

Lymphatic/vascular invasion: No.

Capsular invasion: No.

Tumor extent:

Confined to the thyroid: Yes.

Multifocal: Yes; one microscopic focus (2 mm diameter) is present in the

[page 3 of 4]
contralateral lobe.

Invasion of thyroid cartilage or hyoid bone: No.

Infiltration of adjacent structures: No.

Lymph nodes:

Total number examined: 5

Sites/laterality: Bilateral.

Number positive: 5

Number negative: 0

Extranodal extension: No.

pTNM: pT2N1Mx

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Rule out parathyroid: (FROZEN SECTION PERFORMED)
- Adipose tissue, no parathyroid.

Examining pathologist: [REDACTED]

*****SPECIMEN(S) RECEIVED:*****

A: Parathyroid, REG

B: Thyroid, REG

C: Parathyroid, REG

*****GROSS DESCRIPTION:*****

The specimens are received in three properly labeled containers with the patient's name and accession number.

A. The specimen is designated as "rule out parathyroid" and consists of one fragment of tissue that measures 0.3 x 0.3 x 0.1 cm. The specimen was previously submitted for frozen section and was totally submitted for microscopic evaluation. TE 1

Summary of Cassettes: AF1, adipose tissue

B. The specimen is designated as "total thyroid and left central neck contents" and consists of a 31.9 grams of total thyroid that measures 8.0 x 5.0 x 2.5 cm. The specimen was previously inked as follows: the left lobe was inked black, the right lobe was inked blue, and the isthmus was inked green. The external surface of the thyroid is smooth and shows an irregular area of induration along the anterior surface of the left lobe. The specimen was previously sectioned and reveals an irregular, ill-defined area of grayish, firm, rubbery tissue with areas of hemorrhage and cystic degeneration located in the left lobe that measures 3.5 x 3.0 x 2.5 cm. The lesion shows infiltrative borders and grossly does not seem to invade the thyroid capsule. The lesions do not extend up to the isthmus or the contralateral lobe. The uninvolved surrounding thyroid parenchyma is beefy red-brown and unremarkable. Attached to the right lobe, there is one

[page 4 of 4]
fragment of adipose tissue that measures 4.0 x 1.5 x 1.0 cm. RS 10

Summary of Cassettes: B1-5, tumor with capsule and with adjacent thyroid parenchyma; B6-7, right lobe; B8, isthmus; B9-10, totally submitted additional fragment of adipose tissue

C. The specimen is designated "possible parathyroid from left central neck dissection" and consists of one small fragment of fibroadipose tissue that measures 1.2 x 1.0 x 0.5 cm. The specimen is totally submitted for microscopic evaluation. TE 1

Summary of Cassettes: C1, totally embedded fibroadipose tissue

Gross description by: [REDACTED]

Source: NCI Genomic Data Commons file 425119e6-d31b-431e-8b5e-4a3f35fe4f20 (TCGA-FE-A236.E47EE58C-029A-45DB-8EC1-4AFD3AEB07F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).